Somatic mutation profile of tumor specimen MMRF_2404_1_BM_CD138pos (aliquot MMRF_2404_1_BM_CD138pos_T3_KHS5U_K14031) from MMRF case MMRF_2404, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.1 years (18,306 days).
Specimen MMRF_2404_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c1989a1-3971-4a75-8cfe-68ec3ece2149.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2404_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2404_1_PB_Whole_C1_KHS5U_K14030; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e22c80a-eddd-44b4-99a5-6640df0cbc40

The open-access MAF lists 98 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 38, Missense Mutation 22, Intron 14, Silent 10, 5'UTR 6, 5'Flank 3, Splice Region 2, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 37/124 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CBL | c.1111T>G p.Y371D | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM099544, CM105459, COSV50629681, COSV50630036, COSV50630502; called by muse, mutect2
- DOCK4 | c.1633C>T p.L545F | Missense Mutation (SNP) | VAF 92/145 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV101447917; called by muse, mutect2, varscan2
- GPLD1 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 114/235 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs146221974, COSV99038592; called by muse, mutect2, varscan2
- IGLV1-47 | c.308A>C p.E103A | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as rs755453528; called by muse, mutect2, varscan2
- KIF26A | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768745005; called by muse, mutect2, varscan2
- MKI67 | c.5746G>A p.D1916N | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.108); catalogued as rs779128192, COSV100896394; called by muse, mutect2, varscan2
- NCAN | c.3302G>A p.R1101H | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs372133867; called by muse, mutect2, varscan2
- PCM1 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1441212322; called by muse, mutect2, varscan2
- STOX1 | c.2032G>A p.V678M | Missense Mutation (SNP) | VAF 142/337 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs201271155; called by muse, mutect2, varscan2
- ACAD11 | c.1345T>C p.Y449H | Missense Mutation (SNP) | VAF 173/537 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- C9orf131 | c.2107G>C p.E703Q | Missense Mutation (SNP) | VAF 98/332 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CHSY1 | c.808T>A p.S270T | Missense Mutation (SNP) | VAF 181/305 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- COL12A1 | c.7356G>T p.G2452= | Splice Region (SNP) | VAF 72/184 reads (39%) | called by muse, mutect2, varscan2
- DMRTC2 | c.764C>A p.T255N | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- FAM178B | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- HROB | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- IKZF2 | c.598T>A p.Y200N | Missense Mutation (SNP) | VAF 55/89 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- INTS9 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MYH13 | c.4171G>A p.E1391K | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCBP1 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 74/416 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PLTP | c.-14T>C | Splice Region (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- RASEF | c.1122T>A p.N374K | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF217 | c.688A>G p.S230G | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- ANO6 | c.1437G>A p.S479= | Silent (SNP) | VAF 67/332 reads (20%) | catalogued as rs754675852, COSV57666837; called by muse, mutect2, varscan2
- ASPRV1 | c.519G>C p.G173= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as COSV100208475; called by muse, mutect2, varscan2
- BMP7 | c.105C>T p.N35= | Silent (SNP) | VAF 58/113 reads (51%) | called by muse, mutect2, varscan2
- C9orf131 | c.1743G>C p.L581= | Silent (SNP) | VAF 97/309 reads (31%) | called by muse, mutect2, varscan2
- CRTAC1 | c.855G>A p.V285= | Silent (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- LETM1 | c.1635C>T p.I545= | Silent (SNP) | VAF 49/113 reads (43%) | catalogued as rs374644730, COSV100245125; called by muse, mutect2, varscan2
- MUC16 | c.11700C>T p.S3900= | Silent (SNP) | VAF 57/93 reads (61%) | catalogued as rs1490775602; called by muse, mutect2, varscan2
- PIK3C2G | c.714T>C p.P238= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs932553452; called by muse, mutect2, varscan2
- RYR3 | c.3990C>T p.Y1330= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs531084938, COSV66801553; ClinVar: likely benign; called by muse, mutect2, varscan2
- VPS35 | c.1149C>G p.L383= | Silent (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- AJUBA | c.*2190C>A | 3'UTR (SNP) | VAF 34/69 reads (49%) | called by muse, mutect2, varscan2
- AL117339.4 | c.*703G>T | 3'UTR (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- ALX4 | c.*3962A>C | 3'UTR (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
- BTBD11 | c.*632T>A | 3'UTR (SNP) | VAF 11/67 reads (16%) | catalogued as rs962204308, COSV55024307; called by muse, mutect2, varscan2
- C15orf54 | n.2782G>T | RNA (SNP) | VAF 47/82 reads (57%) | called by muse, mutect2, varscan2
- C9orf152 | c.-422A>C | 5'UTR (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2
- CAV2 | c.338+522G>A | Intron (SNP) | VAF 55/84 reads (65%) | called by muse, mutect2, varscan2
- CCDC57 | c.2241+6153G>A | Intron (SNP) | VAF 36/75 reads (48%) | called by muse, mutect2, varscan2
- CCNH | chr5:87412933 C>T | 5'Flank (SNP) | VAF 45/172 reads (26%) | called by muse, mutect2, varscan2
- CD53 | c.*623A>C | 3'UTR (SNP) | VAF 40/43 reads (93%) | called by muse, mutect2, varscan2
- CDCP1 | chr3:45146392 G>A | 5'Flank (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- CDH19 | c.*1835T>A | 3'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- CDK19 | c.*4118A>C | 3'UTR (SNP) | VAF 16/42 reads (38%) | called by muse, varscan2
- CDK19 | c.*4042T>C | 3'UTR (SNP) | VAF 40/84 reads (48%) | called by muse, varscan2
- CDK19 | c.*4041A>G | 3'UTR (SNP) | VAF 40/84 reads (48%) | called by muse, varscan2
- CIR1 | c.485-32T>C | Intron (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- COL10A1 | c.*1018T>A | 3'UTR (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2
- COL21A1 | c.*338G>T | 3'UTR (SNP) | VAF 27/118 reads (23%) | called by muse, mutect2, varscan2
- CYP2B7P | n.1398C>T | RNA (SNP) | VAF 39/176 reads (22%) | called by muse, mutect2, varscan2
- DIMT1 | c.792+228C>T | Intron (SNP) | VAF 158/353 reads (45%) | called by muse, mutect2, varscan2
- DSCAM | c.*1586C>T | 3'UTR (SNP) | VAF 29/87 reads (33%) | catalogued as rs966417749; called by muse, mutect2, varscan2
- EIF2AK1 | c.*2127A>G | 3'UTR (SNP) | VAF 45/171 reads (26%) | called by muse, mutect2, varscan2
- EIF3A | c.*718T>A | 3'UTR (SNP) | VAF 57/130 reads (44%) | called by muse, mutect2, varscan2
- EIF4A1 | c.73-19A>T | Intron (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- FOXP1 | c.*2561C>T | 3'UTR (SNP) | VAF 92/131 reads (70%) | called by muse, mutect2, varscan2
- FUBP3 | c.191-1709G>A | Intron (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- GJA5 | c.*1546C>G | 3'UTR (SNP) | VAF 166/264 reads (63%) | called by muse, varscan2
- GRIK4 | c.907-2531C>T | Intron (SNP) | VAF 267/412 reads (65%) | called by muse, mutect2, varscan2
- H4C12 | c.*11C>G | 3'UTR (SNP) | VAF 102/228 reads (45%) | catalogued as rs375764291; called by muse, mutect2, varscan2
- IGLV1-47 | c.-26A>G | 5'UTR (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- ISL1 | c.*902A>T | 3'UTR (SNP) | VAF 26/100 reads (26%) | called by muse, mutect2, varscan2
- LPP | c.1240+4305C>A | Intron (SNP) | VAF 66/213 reads (31%) | called by muse, mutect2, varscan2
- LTB | c.163-27C>A | Intron (SNP) | VAF 252/525 reads (48%) | called by muse, mutect2, varscan2
- MAML2 | c.*345G>A | 3'UTR (SNP) | VAF 66/148 reads (45%) | called by muse, varscan2
- MLXIP | c.-43G>A | 5'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as rs1482777871; called by mutect2, varscan2
- MSANTD4 | c.-54A>T | 5'UTR (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- MYADML2 | c.-102-55T>C | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- NOS1 | c.2532-2211T>A | Intron (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2, varscan2
- NXN | c.820+61G>A | Intron (SNP) | VAF 34/79 reads (43%) | catalogued as rs754795821; called by muse, mutect2, varscan2
- PDE1C | c.1892-13192del | Intron (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel, varscan2
- PDE9A | c.*172T>C | 3'UTR (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- PITPNM3 | c.*2376_*2379del | 3'UTR (DEL) | VAF 16/28 reads (57%) | called by mutect2, varscan2
- POLR1D | c.*89G>A | 3'UTR (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- POU2F2 | chr19:42089232 G>A | 3'Flank (SNP) | VAF 16/62 reads (26%) | catalogued as rs1255139462; called by mutect2, varscan2
- PPP1R18 | chr6:30687562 G>A | 5'Flank (SNP) | VAF 66/128 reads (52%) | catalogued as rs1276057300; called by muse, mutect2, varscan2
- PRICKLE1 | c.*836del | 3'UTR (DEL) | VAF 22/45 reads (49%) | catalogued as rs746752965; called by mutect2, varscan2
- RCAN2 | c.-116G>A | 5'UTR (SNP) | VAF 28/102 reads (27%) | catalogued as rs1291262512, COSV100149961; called by muse, mutect2, varscan2
- RPL15 | c.*1336A>G | 3'UTR (SNP) | VAF 38/335 reads (11%) | called by muse, mutect2, varscan2
- SEC14L2 | c.*1064A>C | 3'UTR (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- SENP2 | c.*162T>G | 3'UTR (SNP) | VAF 60/98 reads (61%) | called by muse, mutect2, varscan2
- SLC2A4 | c.*1609A>T | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- SLITRK1 | c.*1312A>G | 3'UTR (SNP) | VAF 35/40 reads (88%) | called by muse, mutect2, varscan2
- SLITRK1 | c.*379G>A | 3'UTR (SNP) | VAF 16/49 reads (33%) | catalogued as rs1007961942; called by muse, mutect2, varscan2
- SPOCK3 | c.*1349T>A | 3'UTR (SNP) | VAF 25/28 reads (89%) | called by muse, mutect2, varscan2
- TBC1D8B | c.*1227dup | 3'UTR (INS) | VAF 38/51 reads (75%) | called by mutect2, pindel, varscan2
- TBX15 | c.*1604T>C | 3'UTR (SNP) | VAF 39/79 reads (49%) | called by muse, mutect2, varscan2
- TIMP4 | c.*65C>T | 3'UTR (SNP) | VAF 34/45 reads (76%) | called by muse, mutect2, varscan2
- TMEM154 | c.*3216T>C | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- TMEM209 | c.*1469T>G | 3'UTR (SNP) | VAF 108/300 reads (36%) | called by muse, mutect2, varscan2
- TTC3 | c.-729T>A | 5'UTR (SNP) | VAF 48/302 reads (16%) | called by muse, mutect2, varscan2
- UNC5C | c.*2108C>T | 3'UTR (SNP) | VAF 31/32 reads (97%) | called by muse, mutect2, varscan2
- UPB1 | c.364+470A>C | Intron (SNP) | VAF 34/94 reads (36%) | called by muse, mutect2, varscan2
- VHL | c.*1308_*1309del | 3'UTR (DEL) | VAF 37/53 reads (70%) | called by mutect2, pindel*, varscan2*
- XPNPEP3 | c.*2722T>G | 3'UTR (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
